Somatic mutation profile of tumor specimen 0DIYSJ from CCDI case PBBWJH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 6.8 years (2,482 days).
Specimen 0DIYSJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1723d40-4c9a-4fb2-93bb-6ac9dfdd6329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIYS7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57df62f0-f1aa-4102-9ce3-20de17f8a303

The open-access MAF lists 56 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Intron 5, Splice Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 967/1031 reads (94%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- BLM | c.3730G>A p.V1244I | Missense Mutation (SNP) | VAF 30/1051 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1249106324, COSV61925212; ClinVar: uncertain significance; called by muse, mutect2
- CXCL1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 516/1068 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.365); catalogued as rs746294684; called by muse, mutect2, varscan2
- INSYN2B | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 77/1310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1009613524; called by muse, mutect2
- KRT74 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 406/2279 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs751221409; called by muse, mutect2, varscan2
- MAP3K1 | c.1337G>T p.C446F | Missense Mutation (SNP) | VAF 800/1794 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68129015; called by mutect2, varscan2
- PCM1 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 194/1614 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as rs1437167491; called by muse, mutect2, varscan2
- SCN11A | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 436/962 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1406348004, COSV56573020; called by muse, varscan2
- SNAP25 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 354/1576 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV99655322; called by mutect2, varscan2
- TENM3 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 449/940 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as rs200203346; called by muse, mutect2, varscan2
- VGLL4 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 291/652 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.71); catalogued as COSV56079360; called by muse, mutect2, varscan2
- ZNF415 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 408/1007 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.284); catalogued as rs753379230; called by muse, mutect2, varscan2
- ZP4 | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 510/1870 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV100850652; called by muse, mutect2, varscan2
- ACSL6 | c.1721A>G p.E574G (on ENST00000379240; = p.E599G on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 733/1654 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 775/2146 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, varscan2
- CEPT1 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 416/1278 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CHD9 | c.6572C>G p.S2191C | Missense Mutation (SNP) | VAF 538/1370 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CLCC1 | c.818C>T p.T273I (on ENST00000356970 / NM_001377464.1; = p.T223I on NM_015127.5) | Missense Mutation (SNP) | VAF 398/1169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKG | c.1196G>A p.C399Y | Missense Mutation (SNP) | VAF 353/1601 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FGFR4 | c.2260-1G>A p.X754_splice | Splice Site (SNP) | VAF 996/1147 reads (87%) | called by muse, mutect2, varscan2
- FLNB | c.4801C>A p.L1601I | Missense Mutation (SNP) | VAF 349/870 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GALNT13 | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 384/1185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM6A | c.3424A>G p.R1142G | Missense Mutation (SNP) | VAF 316/347 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIZ | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 925/2009 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT35 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 389/860 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MS4A14 | c.958T>A p.L320M | Missense Mutation (SNP) | VAF 422/1391 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MSH3 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 648/1777 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NRROS | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 32/938 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2
- PLCH1 | c.4675C>G p.Q1559E (on ENST00000340059 / NM_001130960.2; = p.Q1551E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 353/806 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SOX21 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 99/348 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SOX6 | c.986A>G p.H329R | Missense Mutation (SNP) | VAF 280/1050 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- THNSL2 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 563/1909 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- UBQLN4 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 524/1568 reads (33%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.745); called by muse, varscan2
- UBTD1 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 233/494 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ZP1 | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 248/856 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD50 | c.1668C>A p.G556= | Silent (SNP) | VAF 226/505 reads (45%) | called by muse, mutect2, varscan2
- CACNA1H | c.4299C>T p.I1433= | Silent (SNP) | VAF 318/846 reads (38%) | catalogued as rs764853757, COSV61983560; called by muse, mutect2
- CALML5 | c.324G>A p.A108= | Silent (SNP) | VAF 221/533 reads (41%) | called by muse, mutect2, varscan2
- COQ10A | c.598C>T p.L200= | Silent (SNP) | VAF 837/2324 reads (36%) | catalogued as COSV57525457; called by muse, mutect2, varscan2
- DNAH6 | c.4287C>A p.L1429= | Silent (SNP) | VAF 54/1848 reads (3%) | called by muse, mutect2
- INHBA | c.123C>T p.A41= | Silent (SNP) | VAF 390/1582 reads (25%) | catalogued as COSV54220396, COSV99638110; called by muse, mutect2, varscan2
- LUC7L | c.996C>A p.S332= | Silent (SNP) | VAF 49/962 reads (5%) | called by muse, mutect2
- PHACTR1 | c.1377C>T p.G459= | Silent (SNP) | VAF 441/951 reads (46%) | called by muse, mutect2, varscan2
- PLSCR2 | c.156A>C p.P52= | Silent (SNP) | VAF 38/876 reads (4%) | called by muse, mutect2
- SGCA | c.429C>T p.H143= | Silent (SNP) | VAF 415/1022 reads (41%) | catalogued as rs763446303, COSV100006815; called by muse, mutect2, varscan2
- SLX4IP | c.468T>G p.P156= | Silent (SNP) | VAF 393/1963 reads (20%) | catalogued as COSV100570938; called by muse, mutect2, varscan2
- TAF3 | c.2523A>G p.K841= | Silent (SNP) | VAF 34/966 reads (4%) | called by muse, mutect2
- TCAP | c.102C>G p.P34= | Silent (SNP) | VAF 242/616 reads (39%) | catalogued as rs1060504770, CD1415043, COSV99510833; called by muse, mutect2, varscan2
- TOR3A | c.525C>T p.F175= | Silent (SNP) | VAF 327/963 reads (34%) | called by muse, mutect2, varscan2
- AC021218.1 | n.214G>A | RNA (SNP) | VAF 114/629 reads (18%) | catalogued as rs780132058; called by muse, mutect2, varscan2
- CFAP43 | c.1095+13G>A | Intron (SNP) | VAF 232/591 reads (39%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29726928 G>T | 3'Flank (SNP) | VAF 588/1219 reads (48%) | called by muse, mutect2, varscan2
- NFATC2IP | c.578+34C>G | Intron (SNP) | VAF 160/338 reads (47%) | called by muse, mutect2, varscan2
- P3H2 | c.2034+69T>C | Intron (SNP) | VAF 32/1052 reads (3%) | called by muse, mutect2
- P4HA1 | c.1534+68G>A | Intron (SNP) | VAF 74/131 reads (56%) | called by muse, mutect2, varscan2
- PTBP1 | c.39+70C>G | Intron (SNP) | VAF 134/352 reads (38%) | catalogued as COSV62458694; called by muse, mutect2, varscan2
